Somatic mutation profile of tumor specimen C3L-04081-01 (aliquot CPT0265510008) from CPTAC case C3L-04081, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.6 years (23,222 days).
Specimen C3L-04081-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f929406a-7824-472e-ba68-08551dd6e066.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04081-31 (Blood Derived Normal), aliquot CPT0264060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9386371-5498-49ae-8ecb-ee4c9b4ae9e5

The open-access MAF lists 74 somatic variants for this specimen: 51 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 14, Intron 5, Frame Shift Del 2, Splice Site 2, 3'UTR 2, 3'Flank 1, Nonsense Mutation 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKHD1 | c.10444C>T p.R3482C | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs148617572, CM032336; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 151/263 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555526335, CM115636, COSV52689293, COSV52760406, COSV52970718; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.8620G>C p.A2874P | Missense Mutation (SNP) | VAF 60/452 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs772827989, COSV60924961; called by muse, mutect2
- ANKRD33 | c.343G>A p.V115M (on ENST00000340970 / NM_001304459.2; = p.V240M on NM_182608.4) | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as rs368101868; called by muse, mutect2, varscan2
- AURKC | c.893G>A p.R298Q (on ENST00000302804 / NM_001015878.2; = p.R264Q on NM_003160.3) | Missense Mutation (SNP) | VAF 129/417 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs575228273, COSV57140463; called by muse, mutect2, varscan2
- BTBD11 | c.2324C>T p.A775V (on ENST00000280758 / NM_001018072.2; = p.A312V on NM_001017523.2) | Missense Mutation (SNP) | VAF 96/349 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs371455377; called by muse, mutect2, varscan2
- CACNA1D | c.4864C>T p.R1622W (on ENST00000350061 / NM_001128840.3; = p.R1642W on NM_000720.4) | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145414503; called by muse, mutect2, varscan2
- CAVIN3 | c.542C>A p.T181N | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV58269677; called by muse, mutect2, varscan2
- CHRM3 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 96/249 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1221241600; called by muse, mutect2, varscan2
- CTTNBP2 | c.3895T>A p.S1299T | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.146); catalogued as COSV50489590; called by muse, mutect2, varscan2
- DDX31 | c.903+1G>A p.X301_splice | Splice Site (SNP) | VAF 42/133 reads (32%) | catalogued as rs770031706; called by muse, mutect2, varscan2
- FGB | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV57419556; called by muse, mutect2, varscan2
- FGD3 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as rs371917520; called by muse, mutect2, varscan2
- HTR3E | c.167C>T p.P56L (on ENST00000415389 / NM_001256613.1; = p.P71L on NM_182589.2) | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755326873; called by muse, mutect2, varscan2
- IL2RB | c.455G>T p.W152L | Missense Mutation (SNP) | VAF 99/360 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53428750; called by muse, mutect2, varscan2
- KMT2C | c.2067G>A p.M689I | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100071067, COSV51525799; called by muse, mutect2, varscan2
- MAGEL2 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious, low confidence (0); catalogued as rs1297861557; called by muse, mutect2, varscan2
- OR4B1 | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 92/332 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs996641631; called by muse, mutect2, varscan2
- PCDHGA12 | c.821A>G p.N274S | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.718); catalogued as rs777990962; called by muse, mutect2, varscan2
- PLEKHG4 | c.2636G>A p.R879Q | Missense Mutation (SNP) | VAF 101/287 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as rs143124208, COSV58575705; called by muse, mutect2, varscan2
- PON2 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 48/671 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); catalogued as COSV56002317; called by muse, mutect2
- RXFP2 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 88/340 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs373570227; called by muse, mutect2, varscan2
- SLC6A2 | c.622A>G p.T208A | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.393); catalogued as COSV99574383; called by muse, mutect2
- SPAG16 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs373988564; called by muse, varscan2
- SVEP1 | c.3638G>A p.R1213H | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs371387093; called by muse, mutect2, varscan2
- WDR18 | c.744C>T p.P248= | Splice Region (SNP) | VAF 21/59 reads (36%) | catalogued as rs771858007, COSV52120992; called by muse, mutect2, varscan2
- ZNF596 | c.956G>T p.C319F | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.231); catalogued as COSV57654171; called by muse, mutect2
- CCNL2 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- CX3CR1 | c.1036A>T p.T346S | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DDR1 | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- DLC1 | c.1502+2T>A p.X501_splice (on ENST00000276297 / NM_001348081.2; = p.X64_splice on NM_006094.5) | Splice Site (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- FEZF1 | c.635_660del p.Y212Sfs*34 | Frame Shift Del (DEL) | VAF 72/468 reads (15%) | called by mutect2, pindel
- GJA5 | c.337A>T p.R113W | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2
- GRAMD1C | c.767T>C p.F256S | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.019); called by muse, mutect2
- GUCY2D | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 331/567 reads (58%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IKBKE | c.1202A>C p.K401T | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- INHBE | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 125/4566 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2
- ITFG2 | c.534G>T p.M178I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KLRC1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 75/294 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- LPA | c.2567A>C p.H856P | Missense Mutation (SNP) | VAF 53/392 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LPA | c.1199A>C p.H400P | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- MFSD2B | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 110/445 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- OR2W1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PIK3CG | c.2687T>C p.V896A | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.029); called by muse, mutect2
- PPP4R3C | c.1623G>T p.K541N | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2
- SLC22A2 | c.1196A>T p.D399V | Missense Mutation (SNP) | VAF 11/337 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC22A4 | c.566del p.F189Sfs*25 | Frame Shift Del (DEL) | VAF 145/516 reads (28%) | called by mutect2, pindel, varscan2
- TLE3 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- TMPRSS11A | c.825C>A p.D275E | Missense Mutation (SNP) | VAF 129/376 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TTN | c.73519T>C p.F24507L (on ENST00000591111; = p.F17083L on NM_003319.4) | Missense Mutation (SNP) | VAF 24/86 reads (28%) | PolyPhen benign (0.269); called by muse, mutect2, varscan2
- XK | c.287A>C p.N96T | Missense Mutation (SNP) | VAF 94/283 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- AMY2A | c.162G>T p.G54= | Silent (SNP) | VAF 70/183 reads (38%) | catalogued as COSV101340681; called by muse, mutect2, varscan2
- ARL3 | c.12C>G p.L4= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs780505243; called by muse, varscan2
- CELSR3 | c.8109C>T p.L2703= | Silent (SNP) | VAF 49/195 reads (25%) | catalogued as rs764995199; called by muse, mutect2, varscan2
- COL20A1 | c.921C>T p.G307= | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as rs559281565; called by muse, mutect2, varscan2
- DCBLD2 | c.912G>A p.A304= | Silent (SNP) | VAF 66/451 reads (15%) | catalogued as rs1402235112, COSV58789203; called by muse, mutect2, varscan2
- GPT | c.447G>A p.A149= | Silent (SNP) | VAF 122/254 reads (48%) | catalogued as rs1281174019; called by muse, mutect2, varscan2
- PITPNM2 | c.2985C>T p.H995= | Silent (SNP) | VAF 63/191 reads (33%) | catalogued as rs779899379; called by muse, mutect2, varscan2
- SLC12A2 | c.54C>T p.V18= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1289586585; called by muse, mutect2, varscan2
- SLC1A1 | c.1134G>A p.A378= | Silent (SNP) | VAF 95/355 reads (27%) | catalogued as rs570228124, COSV52058695; called by muse, mutect2, varscan2
- SLITRK4 | c.1806T>A p.T602= | Silent (SNP) | VAF 6/138 reads (4%) | catalogued as COSV62021972; called by muse, mutect2
- SP7 | c.1071G>A p.L357= | Silent (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- TBX3 | c.1053G>A p.Q351= (on ENST00000257566 / NM_016569.4; = p.Q331= on NM_005996.4) | Silent (SNP) | VAF 147/523 reads (28%) | called by muse, mutect2, varscan2
- TIAM1 | c.4521C>T p.D1507= | Silent (SNP) | VAF 75/222 reads (34%) | catalogued as rs1228855775; called by muse, mutect2, varscan2
- ZFYVE9 | c.456C>T p.A152= | Silent (SNP) | VAF 40/133 reads (30%) | catalogued as rs762478632; called by muse, mutect2, varscan2
- AGAP2 | c.3080+37G>A | Intron (SNP) | VAF 67/1691 reads (4%) | called by muse, mutect2
- ALG11 | c.*207C>A | 3'UTR (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- ATG10 | c.454-9714A>T | Intron (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- BOD1P2 | n.82G>A | RNA (SNP) | VAF 8/32 reads (25%) | catalogued as rs1424555178; called by muse, mutect2, varscan2
- CACNA1G | c.*406C>T | 3'UTR (SNP) | VAF 193/676 reads (29%) | catalogued as rs1288518094; called by muse, mutect2, varscan2
- CSTA | c.168+25C>T | Intron (SNP) | VAF 33/180 reads (18%) | catalogued as rs534751699; called by muse, mutect2, varscan2
- MACF1 | c.15832-8226_15832-8203del | Intron (DEL) | VAF 39/200 reads (20%) | called by mutect2, pindel, varscan2
- PCDHB6 | chr5:141156565 G>C | 3'Flank (SNP) | VAF 65/200 reads (33%) | called by muse, mutect2, varscan2
- SUMF2 | c.396+36A>C | Intron (SNP) | VAF 120/491 reads (24%) | catalogued as rs1210636229; called by muse, mutect2, varscan2
